Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A01X, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A01X-01A (Primary Tumor).

TCGA #:

Sample ID #: _____

Diagnosis:

This is an invasive, moderately differentiated adenocarcinoma (colon carcinoma, G 2) with penetration of all layers of the wall (p T 3) and penetration into lymphatic vessels (L 1), furthermore, with reference to the resection margins, with free resection margins in the region of the mucosa, with reference to the central ligature, with normal adipose connective tissue and normal portions of vessels, with reference to the lymph nodes, with two metastases from the carcinoma described above

and the additional polyps are tubulovillous adenomas, of which one also exhibits a transition to a carcinoma (G 2), with infiltration of the muscularis (p T 2).

furthermore, there are two lymph node metastases (2/14) and free resection margins and free ligature portions.

Tumor classification:

ICDO-DA-M 8140/3

G 2

p T 3, L 1, p N 1, M x.

ICD-0-3

adenocarcinoma, NOS 8140/3

Site: sigmoid colon, (pw CRC) 3/30/11
C18.7

Source: NCI Genomic Data Commons file 2d885f91-8f84-4277-9bd7-0a86afa2a69c (TCGA-AA-A01X.1FD84A23-A23D-465B-9D2D-83928659BA60.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).